CCDI case PBCKST — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Specialized Gonadal Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/ccd5cfa0-d0ae-4a8f-b69e-3a1d6f18bfc2

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Sex cord-gonadal stromal tumor, NOS: ICD-O-3 morphology code: 8590/1; Tissue or organ of origin: Ovary; Age at diagnosis: 16.3 years (5,948 days).

Biospecimens (3 samples)
- Samples 0DU9MJ, 0DU9MX (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU9NE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
